Gene-level copy-number profile of tumor specimen TCGA-D5-6537-01A from TCGA case TCGA-D5-6537, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 64.0 years (23,381 days).
Specimen TCGA-D5-6537-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.6954e54a-b2d2-45bd-b242-27fcfa60d4eb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D5-6537-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/782430b6-887f-4ed2-b0cf-c1bc10aec6b3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 221; copy number 2: 40,530; copy number 3: 14,134; copy number 4: 2,828; copy number 5: 1,612; copy number 6: 161; copy number 7: 319.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D5-6537-01A-11D-1717-01): tumor purity 0.8, ploidy 2.38, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,058 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:38,195,703–41,786,931, 207 genes, copy number 6–7 (broad region; genes not listed).
- chr17:48,762,235–81,648,465, 952 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr20:30,214,765–64,313,132, 899 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 221. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
